Gene-level copy-number profile of tumor specimen TCGA-DK-AA6R-01A from TCGA case TCGA-DK-AA6R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,196 days).
Specimen TCGA-DK-AA6R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.bb2a1fe7-bb80-4dc6-a2db-f29cdfad7bd0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA6R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa401ae5-a432-460b-b0c1-2efbed614f30

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 707; copy number 2: 21,620; copy number 3: 24,186; copy number 4: 10,947; copy number 5: 1,580; copy number 6: 411; copy number 7: 127; copy number 8: 95; copy number 9: 9; copy number 10: 30; copy number 11: 48; copy number 12: 21; copy number 13: 8; copy number 19: 23; copy number 22: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA6R-01A-11D-A42D-01): tumor purity 0.58, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 364 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:89,700,345–89,838,315, 1 gene, copy number 7 (within-gene range 4–7): SNCA.
- chr4:89,836,408–89,999,409, 3 genes, copy number 7: SNCA-AS1, MMRN1, AC105445.1.
- chr6:19,290,319–21,602,383, 32 genes, copy number 7–13: AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr8:37,421,341–40,016,391, 78 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr10:4,650,158–6,823,789, 64 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:25,647,570–25,732,935, 3 genes, copy number 22: GPN3P1, LINC00836, HIRAP1.
- chr10:49,296,112–50,965,220, 44 genes, copy number 7–12: C10orf71-AS1, C10orf71, DRGX, AL138760.1, ERCC6, HMGB1P50, CHAT, SLC18A3, C10orf53, OGDHL, MAPK6P6, RPL21P89, PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2.
- chr10:51,062,579–51,320,660, 5 genes, copy number 10: AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3.
- chr11:26,188,842–26,663,289, 1 gene, copy number 11 (within-gene range 2–11): ANO3.
- chr11:26,427,051–29,064,322, 32 genes, copy number 11 (within-gene range 3–11): AC079064.1, MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P.
- chr11:33,376,108–33,674,102, 1 gene, copy number 19 (within-gene range 2–19): KIAA1549L.
- chr11:33,665,220–35,420,063, 38 genes, copy number 10–19 (within-gene range 2–19): AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1.
- chr16:20,208,925–21,550,373, 47 genes, copy number 7–9: AC092132.1, SNRPEP3, GP2, UMOD, PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1, DNAH3, AC008551.1, TMEM159, AF001550.1, ZP2, ANKS4B, CRYM, AF001550.2, CRYM-AS1, AC008740.1, SNX29P1, AC008740.2, NPIPB3, SMG1P3, MIR3680-1, AC005632.6, SLC7A5P2, AC005632.5, AC005632.2, AC005632.4.
- chr16:22,206,278–22,613,483, 15 genes, copy number 11 (within-gene range 4–11): EEF2K, AC009034.1, POLR3E, AC092338.3, CDR2, AC092338.1, AC092338.2, MFSD13B, RRN3P3, SMG1P1, NPIPB5, AC106788.1, OTOAP1, AC009021.2, AC009021.1.

Autosomal genes at a single copy (total copy number 1): 707. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
